Gene-level copy-number profile of specimen HCM-BROD-0219-C15-85A from HCMI case HCM-BROD-0219-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.1 years (24,891 days).
Specimen HCM-BROD-0219-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b66e8223-2f79-4b81-bab2-08991ef8aafd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0219-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/fb3a9ed4-a8c2-4c6a-9f65-939e6658ae37

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 507; copy number 1: 1,200; copy number 2: 8,237; copy number 3: 16,007; copy number 4: 15,598; copy number 5: 10,115; copy number 6: 3,490; copy number 7: 2,703; copy number 8: 182; copy number 9: 448; copy number 10: 14; copy number 11: 118; copy number 12: 15; copy number 13: 7; copy number 15: 69; copy number 16: 12; copy number 22: 31; copy number 23: 8; copy number 27: 29; copy number 30: 9; copy number 32: 3; copy number 33: 9; copy number 36: 2; copy number 37: 2; copy number 43: 81; copy number 51: 4.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:125,344,969–125,933,832, 3 genes (within-gene range 0–2): AC010099.2, PPIAP93, AC003975.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,746 genes in 65 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,126,974–121,185,539, 31 genes, copy number 7–11 (within-gene range 6–11): RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B.
- chr1:143,419,625–143,652,215, 11 genes, copy number 7: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P.
- chr1:149,048,576–149,747,818, 20 genes, copy number 7: AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P.
- chr1:163,468,496–168,495,685, 100 genes, copy number 7–8 (broad region; genes not listed).
- chr2:59,217,708–62,262,671, 66 genes, copy number 11–51 (within-gene range 5–51) (broad region; genes not listed).
- chr2:89,266,494–97,664,044, 203 genes, copy number 9 (broad region; genes not listed).
- chr4:72,807,267–74,316,789, 36 genes, copy number 7–8: HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN.
- chr4:143,559,457–144,343,750, 8 genes, copy number 7–11 (within-gene range 6–11): AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2.
- chr4:144,646,156–146,243,669, 34 genes, copy number 7 (within-gene range 5–7): HHIP, AC098588.1, ANAPC10, HSPD1P5, AC109811.1, AC109811.2, RN7SKP235, ABCE1, OTUD4, Y_RNA, RPS23P4, LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1.
- chr4:157,637,687–159,777,828, 38 genes, copy number 7–8: AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233.
- chr5:26,382,519–45,895,970, 277 genes, copy number 7–8 (broad region; genes not listed).
- chr6:9,596,110–22,654,455, 176 genes, copy number 7–15 (within-gene range 4–15) (broad region; genes not listed).
- chr6:98,780,257–99,615,578, 16 genes, copy number 9–13: AL589826.1, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13.
- chr6:99,918,519–111,606,906, 165 genes, copy number 7–22 (broad region; genes not listed).
- chr6:115,633,540–117,602,542, 40 genes, copy number 11: LINC02534, FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4, DSE, AL050331.1, TSPYL1, Z84488.1, CBX3P9, KRT18P22, CALHM6-AS1, CALHM6, AL445224.1, TRAPPC3L, CALHM5, CALHM4, RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A, RFX6, RPS29P13, RNA5SP214, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P, GOPC.
- chr6:118,460,772–119,182,745, 12 genes, copy number 11 (within-gene range 5–11): CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B.
- chr6:125,119,049–126,258,355, 14 genes, copy number 11: TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr6:128,883,138–136,195,574, 126 genes, copy number 8–11 (within-gene range 6–11) (broad region; genes not listed).
- chr6:142,058,330–144,853,034, 48 genes, copy number 9: NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1, AL513475.1, AL513475.2.
- chr7:52,165,235–57,275,197, 130 genes, copy number 23–43 (broad region; genes not listed).
- chr7:63,291,518–63,585,075, 25 genes, copy number 7–10: ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2.
- chr7:63,876,341–64,182,893, 35 genes, copy number 7: AC092634.2, AC092634.4, GABPAP, LINC02848, NMD3P1, AC092634.3, AC092634.8, SLC25A1P3, VN1R34P, ARAFP1, AC092634.7, VN1R35P, VN1R36P, AC092634.1, AC092634.6, ZNF722P, LINC01005, AC115220.1, ZNF727, TRIM60P17, GUSBP6, MTND4P2, MTND4LP2, MTND3P2, MTCO3P8, MTATP6P18, MTCO2P8, MTCO1P8, MTND2P4, MTND1P2, AC091685.1, AC091685.2, VN1R37P, VN1R38P, SAPCD2P1.
- chr8:9,899,871–12,665,588, 102 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr8:39,522,976–42,844,876, 68 genes, copy number 8–33 (broad region; genes not listed).
- chr11:44,047,981–49,434,438, 162 genes, copy number 7 (broad region; genes not listed).
- chr12:9,898,673–10,030,606, 7 genes, copy number 7: CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2.
- chr12:10,212,458–10,599,669, 17 genes, copy number 7: GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P.
- chr12:10,699,089–11,590,369, 45 genes, copy number 7: YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252.
- chr12:14,612,632–15,602,175, 22 genes, copy number 7 (within-gene range 6–7): GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1.
- chr12:15,882,387–16,992,083, 14 genes, copy number 7: STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16.
- chr12:17,479,446–19,108,183, 14 genes, copy number 7: AC048352.1, LINC02378, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1.
- chr12:21,264,600–22,618,868, 27 genes, copy number 7 (within-gene range 6–7): SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1.
- chr12:24,949,163–27,446,625, 55 genes, copy number 7 (within-gene range 6–7): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1.
- chr12:27,696,388–27,824,382, 13 genes, copy number 7: AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3.
- chr12:28,133,249–29,497,686, 20 genes, copy number 7–8: CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1.
- chr12:30,169,881–30,802,602, 11 genes, copy number 7 (within-gene range 6–7): AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, CAPRIN2, AC010198.1, LINC00941.
- chr12:31,363,481–32,396,147, 41 genes, copy number 7: LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA.
- chr12:32,679,200–33,455,452, 18 genes, copy number 7: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1.
- chr20:87,250–64,327,972, 1,401 genes, copy number 7 (broad region; genes not listed).
- chr21:7,744,962–9,027,329, 38 genes, copy number 7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9.

Autosomal genes at a single copy (total copy number 1): 694. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
